Somatic mutation profile of tumor specimen MMRF_2118_1_BM_CD138pos (aliquot MMRF_2118_1_BM_CD138pos_T1_KHS5U_L08660) from MMRF case MMRF_2118, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,204 days).
Specimen MMRF_2118_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfbb6d25-1c63-4bcb-8603-8ae4dd22829f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2118_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2118_1_PB_Whole_C2_KHS5U_L08661; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c89f5d5-c7be-4a52-a7f5-682b6a428d4d

The open-access MAF lists 144 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 37, Silent 21, Intron 14, Frame Shift Del 6, Nonsense Mutation 5, 3'Flank 4, RNA 3, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS2 | c.3083G>A p.W1028* | Nonsense Mutation (SNP) | VAF 109/201 reads (54%) | catalogued as rs1432114940; called by muse, mutect2, varscan2
- CCER1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 89/92 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1304055911, COSV62646111; called by muse, mutect2, varscan2
- CLEC16A | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs376422391; called by muse, mutect2, varscan2
- CSMD3 | c.1661G>A p.G554E (on ENST00000297405 / NM_001363185.1; = p.G450E on NM_052900.3) | Missense Mutation (SNP) | VAF 20/590 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs1361326399, COSV52183814; called by muse, mutect2
- GCFC2 | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV58081489; called by muse, mutect2
- GUCY1B1 | c.962T>C p.F321S | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100025270; called by muse, mutect2, varscan2
- H3C3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs752518862; called by muse, mutect2, varscan2
- IGHJ4 | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 43/46 reads (93%) | PolyPhen benign (0.1); catalogued as rs376281741; called by muse, varscan2
- IGHV2-70D | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 138/270 reads (51%) | catalogued as rs1256056776; called by muse, varscan2
- IGLL5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs6003368, COSV73248992, COSV73250942, COSV73250989, COSV73251049; called by muse, varscan2
- IGLL5 | c.288_291del p.C96Wfs*12 | Frame Shift Del (DEL) | VAF 110/169 reads (65%) | catalogued as rs745343783; called by pindel*, varscan2
- IRX5 | c.250-5C>T | Splice Region (SNP) | VAF 71/318 reads (22%) | catalogued as rs752267937; called by muse, mutect2, varscan2
- LONRF2 | c.1989G>A p.W663* | Nonsense Mutation (SNP) | VAF 31/285 reads (11%) | catalogued as COSV66542750; called by muse, mutect2, varscan2
- LRRC8E | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs763230673, COSV60719046; called by muse, mutect2, varscan2
- MELK | c.1860A>C p.K620N | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as rs762498744; called by muse, mutect2, varscan2
- MGA | c.4474C>A p.R1492S | Missense Mutation (SNP) | VAF 115/335 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV54949325; called by muse, mutect2, varscan2
- NRK | c.4496A>G p.D1499G | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs752164569; called by muse, mutect2
- OR2M3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs765663539, COSV71758955; called by muse, mutect2, varscan2
- RDH10 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1210602500; called by muse, mutect2, varscan2
- ROGDI | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs768480593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.4003G>A p.V1335I | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.858); catalogued as rs1049580052; called by muse, mutect2
- SEC61A2 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53653756, COSV53655892; called by muse, mutect2, varscan2
- TRAF3 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs749819593; called by muse, mutect2, varscan2
- VPS8 | c.2189+1G>A p.X730_splice (on ENST00000625842 / NM_001349294.1; = p.X728_splice on NM_015303.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 55/117 reads (47%) | catalogued as rs780458579; called by muse, mutect2, varscan2
- AIM2 | c.721A>T p.N241Y | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BCOR | c.3587T>C p.V1196A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BHLHE41 | c.129T>G p.D43E | Missense Mutation (SNP) | VAF 99/145 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- BLOC1S2 | c.102A>C p.E34D | Missense Mutation (SNP) | VAF 287/604 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNN1 | c.13C>A p.H5N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL4B | c.1881A>T p.K627N | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP4A11 | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DEK | c.693T>A p.S231R | Missense Mutation (SNP) | VAF 21/735 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- DRICH1 | c.345A>T p.E115D | Missense Mutation (SNP) | VAF 363/854 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.801); called by muse, varscan2
- ERI2 | c.785A>T p.Q262L | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETAA1 | c.412_413insT p.N138Ifs*8 | Frame Shift Ins (INS) | VAF 32/180 reads (18%) | called by mutect2, pindel, varscan2
- FBXL18 | c.1249T>C p.S417P | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- GRM1 | c.3455G>A p.R1152H | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HEPACAM2 | c.565G>T p.V189F (on ENST00000394468 / NM_001039372.4; = p.V177F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/363 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- KDM5C | c.762del p.D254Efs*18 | Frame Shift Del (DEL) | VAF 36/117 reads (31%) | called by mutect2, pindel, varscan2
- MCM9 | c.2102T>C p.I701T | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFAP3 | c.141C>G p.S47R | Missense Mutation (SNP) | VAF 253/577 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO9A | c.2995_3000+5del p.X999_splice | Splice Site (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel
- NR4A2 | c.1096A>C p.S366R | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OR51B4 | c.607_610del p.T203Sfs*3 | Frame Shift Del (DEL) | VAF 50/364 reads (14%) | called by mutect2, varscan2
- PDE8B | c.2307_2308del p.Q769Hfs*9 | Frame Shift Del (DEL) | VAF 83/226 reads (37%) | called by mutect2, pindel, varscan2
- PITX1 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCH2 | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 80/198 reads (40%) | called by muse, mutect2, varscan2
- PRRT3 | c.2329_2341del p.S777Dfs*19 | Frame Shift Del (DEL) | VAF 47/93 reads (51%) | called by mutect2, varscan2
- PWWP2B | c.698A>T p.K233M | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SORBS2 | c.392C>T p.P131L (on ENST00000284776 / NM_021069.5; = p.P177L on NM_003603.6) | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPAG5 | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 46/295 reads (16%) | called by muse, mutect2, varscan2
- SQOR | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2
- TMEM86A | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 192/366 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TOX | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 79/478 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TRAF3 | c.264T>G p.C88W | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TRBV28 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TRIM31 | c.1235T>A p.L412Q | Missense Mutation (SNP) | VAF 120/676 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TRRAP | c.7001G>T p.R2334L (on ENST00000359863 / NM_001244580.1; = p.R2316L on NM_003496.3) | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZKSCAN2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZMYM2 | c.1116_1117del p.V374Yfs*3 | Frame Shift Del (DEL) | VAF 106/160 reads (66%) | called by pindel, varscan2
- ZNF304 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ATP8B2 | c.1830G>T p.L610= (on ENST00000672630; = p.L577= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 102/329 reads (31%) | called by muse, mutect2, varscan2
- CCDC185 | c.381G>A p.L127= | Silent (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- CEP126 | c.363C>T p.A121= | Silent (SNP) | VAF 32/243 reads (13%) | called by muse, mutect2, varscan2
- COL5A2 | c.1821C>T p.I607= | Silent (SNP) | VAF 93/180 reads (52%) | called by muse, mutect2, varscan2
- DOCK10 | c.6129T>G p.L2043= | Silent (SNP) | VAF 230/509 reads (45%) | called by muse, mutect2, varscan2
- GALK1 | c.1176G>A p.L392= | Silent (SNP) | VAF 91/157 reads (58%) | catalogued as COSV99564132; called by muse, mutect2, varscan2
- GRM5 | c.276C>A p.G92= | Silent (SNP) | VAF 201/424 reads (47%) | called by muse, mutect2, varscan2
- IFT122 | c.504G>A p.K168= | Silent (SNP) | VAF 48/464 reads (10%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.96A>G p.K32= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs1326050117; called by muse, varscan2
- LAD1 | c.879G>A p.Q293= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.4269G>A p.K1423= | Silent (SNP) | VAF 112/116 reads (97%) | catalogued as COSV101280805; called by muse, mutect2, varscan2
- LZIC | c.303A>G p.K101= | Silent (SNP) | VAF 270/602 reads (45%) | called by muse, mutect2, varscan2
- MRPS12 | c.132G>A p.R44= | Silent (SNP) | VAF 256/549 reads (47%) | called by muse, mutect2, varscan2
- MYO1H | c.2379C>T p.I793= | Silent (SNP) | VAF 64/207 reads (31%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1611C>T p.S537= | Silent (SNP) | VAF 200/380 reads (53%) | called by muse, mutect2, varscan2
- POU5F1B | c.678C>A p.L226= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV66967074, COSV66967092; called by muse, mutect2, varscan2
- RARRES1 | c.399G>A p.K133= | Silent (SNP) | VAF 121/560 reads (22%) | called by muse, mutect2, varscan2
- RTEL1 | c.849G>A p.L283= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as rs1278146543; called by muse, mutect2, varscan2
- SLC1A4 | c.393C>T p.L131= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as COSV52235987; called by muse, mutect2, varscan2
- TRABD2B | c.795C>T p.F265= | Silent (SNP) | VAF 41/214 reads (19%) | called by muse, mutect2, varscan2
- USP48 | c.1563G>A p.P521= | Silent (SNP) | VAF 44/418 reads (11%) | catalogued as rs574686409; called by muse, mutect2, varscan2
- AC024651.2 | n.1634G>A | RNA (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- AGBL1 | c.*75A>G | 3'UTR (SNP) | VAF 178/402 reads (44%) | catalogued as rs1386619521; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4951G>A | Intron (SNP) | VAF 14/168 reads (8%) | catalogued as rs763184590; called by muse, mutect2
- ARHGAP19 | c.*1044G>A | 3'UTR (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- C11orf87 | c.*1609T>C | 3'UTR (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- CALHM5 | c.*741_*746del | 3'UTR (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- CBX6 | c.*1518G>C | 3'UTR (SNP) | VAF 60/551 reads (11%) | called by muse, mutect2, varscan2
- CCDC140 | n.1410A>T | RNA (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- CD274 | c.790+121C>T | Intron (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- CD44 | c.*717G>T | 3'UTR (SNP) | VAF 63/113 reads (56%) | called by muse, mutect2, varscan2
- CDK20 | c.*552G>A | 3'UTR (SNP) | VAF 12/250 reads (5%) | catalogued as rs954163213; called by muse, mutect2
- CENPC | c.-131C>A | 5'UTR (SNP) | VAF 25/142 reads (18%) | catalogued as rs867125848; called by muse, mutect2, varscan2
- CFHR3 | c.614-768A>G | Intron (SNP) | VAF 44/45 reads (98%) | called by muse, mutect2, varscan2
- CGREF1 | chr2:27100436 T>A | 3'Flank (SNP) | VAF 146/286 reads (51%) | called by muse, mutect2, varscan2
- CORO6 | c.*674A>G | 3'UTR (SNP) | VAF 61/390 reads (16%) | called by muse, mutect2, varscan2
- DCST1 | c.1869+829C>T | Intron (SNP) | VAF 53/313 reads (17%) | called by muse, mutect2, varscan2
- DDN | c.*590T>A | 3'UTR (SNP) | VAF 161/166 reads (97%) | called by muse, mutect2, varscan2
- DDX51 | c.*1235C>G | 3'UTR (SNP) | VAF 118/184 reads (64%) | called by muse, mutect2, varscan2
- DNER | c.*637G>T | 3'UTR (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- EBF2 | c.*559del | 3'UTR (DEL) | VAF 62/161 reads (39%) | catalogued as rs1393673189; called by mutect2, pindel, varscan2
- EPHA7 | c.*1608A>C | 3'UTR (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- EXOC6 | c.458+140A>C | Intron (SNP) | VAF 129/254 reads (51%) | called by muse, mutect2, varscan2
- FAM13C | c.1332+354T>A | Intron (SNP) | VAF 94/191 reads (49%) | called by muse, mutect2, varscan2
- FAM155A | c.*202T>C | 3'UTR (SNP) | VAF 115/118 reads (97%) | called by muse, mutect2, varscan2
- FOXK1 | c.*6289G>C | 3'UTR (SNP) | VAF 55/337 reads (16%) | catalogued as rs1042722690; called by muse, mutect2, varscan2
- GABRB3 | chr15:26773661 C>T | 5'Flank (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- GNL1 | c.1099+95C>T | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- GPR176 | c.*1263G>A | 3'UTR (SNP) | VAF 100/225 reads (44%) | called by muse, mutect2, varscan2
- HNRNPA1 | chr12:54280232 G>A | 5'Flank (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- IGLV4-3 | chr22:22872034 ins CGGC | 3'UTR (INS) | VAF 67/70 reads (96%) | called by mutect2, pindel, varscan2
- ITGA2 | c.*1205A>C | 3'UTR (SNP) | VAF 71/134 reads (53%) | called by muse, mutect2, varscan2
- KLHL23 | c.*470C>T | 3'UTR (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
- LPP | c.1240+4318G>A | Intron (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- MAGEC1 | c.*263T>A | 3'UTR (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- MKX | c.*1780G>A | 3'UTR (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- MROH9 | c.*275C>T | 3'UTR (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- MS4A4A | c.42-1996C>T | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- NEK7 | c.*390T>C | 3'UTR (SNP) | VAF 99/188 reads (53%) | catalogued as rs990602080; called by muse, mutect2, varscan2
- NRF1 | chr7:129756762 T>C | 3'Flank (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+3245G>A | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NSD2 | c.1882-3459G>T | Intron (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87873557 C>G | 3'Flank (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- OPLAH | c.*20C>G | 3'UTR (SNP) | VAF 108/210 reads (51%) | called by muse, mutect2
- OR7A2P | n.449G>C | RNA (SNP) | VAF 13/483 reads (3%) | called by muse, mutect2
- PALLD | c.*32+98G>A | Intron (SNP) | VAF 111/755 reads (15%) | catalogued as rs1560938752; called by muse, mutect2, varscan2
- PDPR | c.1868-65G>C | Intron (SNP) | VAF 61/314 reads (19%) | called by muse, mutect2
- PPP2R2D | c.*699T>G | 3'UTR (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- PRKG1 | c.*1831A>T | 3'UTR (SNP) | VAF 71/143 reads (50%) | called by muse, mutect2, varscan2
- PTAFR | chr1:28148167 C>G | 3'Flank (SNP) | VAF 76/236 reads (32%) | called by muse, mutect2, varscan2
- PVR | c.*75A>G | 3'UTR (SNP) | VAF 123/235 reads (52%) | catalogued as rs1357153841; called by muse, mutect2, varscan2
- RUBCN | c.*3208C>T | 3'UTR (SNP) | VAF 17/198 reads (9%) | catalogued as rs937023650; called by muse, mutect2
- SCARA3 | c.*875C>T | 3'UTR (SNP) | VAF 117/242 reads (48%) | called by muse, mutect2, varscan2
- SUOX | c.-10-472G>A | Intron (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- TMEM127 | c.*2864T>A | 3'UTR (SNP) | VAF 75/236 reads (32%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*2019C>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs1054675960; called by muse, mutect2
- TPRG1 | c.*4393C>A | 3'UTR (SNP) | VAF 82/172 reads (48%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*460G>A | 3'UTR (SNP) | VAF 41/280 reads (15%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.*201T>C | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2
- WWC2 | c.*3812C>T | 3'UTR (SNP) | VAF 330/660 reads (50%) | catalogued as COSV100033035; called by muse, mutect2, varscan2
- WWTR1 | c.*2364A>C | 3'UTR (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- ZNF398 | c.*2717A>C | 3'UTR (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
